Gene-level copy-number profile of tumor specimen C3L-00081-01 from CPTAC case C3L-00081, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 62.0 years (22,629 days).
Specimen C3L-00081-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7694fc70-0e42-403d-8f43-249a24e7f8e1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00081-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/7c07da7a-1113-4d54-aa46-907970c21e4b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 105; copy number 1: 88; copy number 2: 73; copy number 3: 16,214; copy number 4: 11,207; copy number 5: 11,553; copy number 6: 13,589; copy number 7: 1,637; copy number 8: 2,246; copy number 9: 240; copy number 10: 1; copy number 11: 23; copy number 12: 682; copy number 14: 557; copy number 15: 40; copy number 17: 37; copy number 19: 1; copy number 23: 13; copy number 25: 6; copy number 26: 21; copy number 29: 4; copy number 31: 16; copy number 36: 12; copy number 38: 4; copy number 40: 9; copy number 41: 1; copy number 43: 9; copy number 49: 2; copy number 51: 1; copy number 53: 3.

Homozygous deletions (total copy number 0; autosomes only): 105 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr2:140,898,423–141,208,376, 4 genes (within-gene range 0–3): LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:20,999,509–26,892,803, 82 genes (broad region; genes not listed).
- chr11:50,246,554–50,422,316, 7 genes: PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.
- chr11:55,602,360–55,686,160, 7 genes: OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,565 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,712,115–46,812,574, 2 genes, copy number 7 (within-gene range 3–7): AC109583.1, PRSS50.
- chr3:46,742,092–46,812,558, 5 genes, copy number 7 (within-gene range 3–7): PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr3:93,980,139–94,055,678, 1 gene, copy number 7 (within-gene range 5–7): ARL13B.
- chr3:94,014,365–138,834,928, 727 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr3:138,825,063–198,123,232, 1,018 genes, copy number 8–12 (broad region; genes not listed).
- chr4:49,486,926–49,557,400, 8 genes, copy number 7: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1.
- chr5:58,198–45,895,970, 679 genes, copy number 8 (broad region; genes not listed).
- chr5:69,985,204–70,555,266, 13 genes, copy number 7: CDH12P2, SERF1B, SMN2, AC140134.1, NAIPP2, CDH12P3, AC138866.1, GUSBP14, GTF2H2B, AC146944.2, NAIPP1, AC146944.1, GUSBP15.
- chr6:170,615,515–170,738,536, 1 gene, copy number 11 (within-gene range 4–11): AL672310.1.
- chr6:170,736,173–170,737,777, 1 gene, copy number 11: AL731684.1.
- chr8:57,492,884–58,204,279, 9 genes, copy number 7: AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26.
- chr8:68,330,955–134,390,487, 930 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:142,834,247–142,916,506, 1 gene, copy number 7 (within-gene range 6–7): GML.
- chr8:142,872,356–145,066,685, 137 genes, copy number 7 (broad region; genes not listed).
- chr9:29,317,833–30,575,012, 5 genes, copy number 7: AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1.
- chr11:69,641,156–73,761,137, 143 genes, copy number 12–53 (broad region; genes not listed).
- chr12:66,767–39,467,345, 853 genes, copy number 8–11 (broad region; genes not listed).
- chr14:18,333,726–19,700,650, 68 genes, copy number 7 (broad region; genes not listed).
- chr16:34,941,977–55,750,111, 291 genes, copy number 7–14 (broad region; genes not listed).
- chr16:55,802,851–70,480,274, 392 genes, copy number 12–19 (broad region; genes not listed).
- chr17:46,243,606–46,757,464, 13 genes, copy number 7 (within-gene range 6–7): MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF.
- chr18:46,917,492–47,102,243, 7 genes, copy number 7 (within-gene range 6–7): KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2, AC012254.5.
- chr18:80,157,232–80,247,514, 1 gene, copy number 7 (within-gene range 6–7): PARD6G.
- chr18:80,183,680–80,202,992, 1 gene, copy number 7: AC139100.1.
- chr20:87,250–268,857, 7 genes, copy number 8: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1.
- chr20:316,860–12,381,255, 252 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 88. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
